Surgical pathology report (de-identified scan), TCGA case TCGA-SR-A6MP, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Tufts Medical Center, specimen TCGA-SR-A6MP-01A (Primary Tumor).

Specimen:
Procedure:
Accessioned:
Reported:
Submitting Phys:

Patient:
Medical Record #:
DOB/Age/Sex: (Age:) F
Location/Clinic:

Surgical Pathology Report

Final Diagnosis

LEFT ADRENAL GLAND, RESECTION:
- PHEOCHROMOCYTOMA.

COMMENT: There is no necrosis, mitotic figures are not seen and occasional hyaline globules are observed. The tumor is surrounded by a fibrous capsule which, in one area, contains attenuated, residual adrenal cortex. The tumor appears completely excised and there is no definitive evidence of tumor protruding into blood vessels associated with thrombus or intact endothelium over protruding tumor.

***Report Electronically Signed By

This certifies that the pathologist named above has personally conducted a microscopic examination (or gross examination only, where stated) of the described specimen(s) and has rendered or confirmed the final diagnosis(es).

Clinical History

Benign adrenal neoplasm.

Pre-Operative Diagnosis

{Not Provided}

Post-Operative Diagnosis

{Not Provided}

Gross Description

A. LEFT ADRENAL GLAND (FRESH): The specimen, labeled with the patient's name and accession number, consists of a round soft tan-white to red and focally hyperemic mass weighing 125 grams and measuring 7 x 7 x 5 cm. The specimen is inked black and serially sectioned to reveal a fleshy, mottled, tan-white to red-brown cut surface with a finely granular appearance. The mass appears to be entirely enclosed within a capsule less than 0.1 cm in thickness. A sample of tissue is removed for research studies. Representative sections are submitted in cassettes A1-7.

Site	6/20/13	Yes	No
I.PAA Discrepancy			✓

Source: NCI Genomic Data Commons file 5a8d8e44-4634-45af-a9a3-0a60de8294d1 (TCGA-SR-A6MP.DA48277C-4A83-48FC-8BE4-326B030235FD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).